Somatic mutation profile of tumor specimen BA2490D (aliquot aq-BA2490D) from BEATAML1.0 case 2544, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,611 days).
Specimen BA2490D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75fddf8c-04c2-4a4a-ae8c-568b3daf0ed1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2475D (Solid Tissue Normal), aliquot aq-BA2475D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2975f0d7-e730-4ba5-b129-c4f4ffe5a978

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 26/376 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SUPT16H | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.11); catalogued as COSV99360141; called by muse, mutect2
- BCOR | c.4819+1G>C p.X1607_splice (on ENST00000378444 / NM_001123385.2; = p.X1573_splice on NM_017745.6) | Splice Site (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- KIAA1109 | c.8186C>A p.T2729K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.015); called by muse, mutect2
- MBOAT4 | c.393G>T p.T131= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- RBM4B | c.702G>T p.A234= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100026586; called by muse, mutect2
- TMPO | chr12:98537616 T>A | 3'Flank (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
